Somatic mutation profile of cancer-model specimen HCM-BROD-0569-C43-85M (Adherent Cell Line, passage 10; aliquot HCM-BROD-0569-C43-85M-01D-A80U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0569-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 78.3 years (28,586 days).
Specimen HCM-BROD-0569-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78a519bb-c78b-4703-a5e0-32baa574c17e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0569-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0569-C43-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67b65aeb-d2f0-45c3-b5bb-9fa556a956ed

The open-access MAF lists 3,802 somatic variants for this specimen: 2,465 protein-altering or splice-affecting, 1,182 silent, 155 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,248, Silent 1,182, Nonsense Mutation 146, Intron 89, Splice Region 35, 5'Flank 24, Splice Site 17, 3'UTR 16, Frame Shift Del 11, 3'Flank 9, RNA 9, 5'UTR 8.

Variants (750 of 3,802; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 82/319 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72653753, CM053088; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID2 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 96/289 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57595738; called by muse, mutect2, varscan2
- ATP1A3 | c.2806G>A p.D936N (on ENST00000545399 / NM_001256214.2; = p.D923N on NM_152296.5) | Missense Mutation (SNP) | VAF 274/276 reads (99%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.57); catalogued as rs267606670, CM094577, CM127594, COSV57487334; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CRB1 | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 96/380 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs267598278, COSV66329373; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.6562C>T p.R2188* | Nonsense Mutation (SNP) | VAF 92/487 reads (19%) | catalogued as rs200497972, COSV63281417; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYCN | c.1192C>T p.R398W | Missense Mutation (SNP) | VAF 248/463 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057517770, COSV55258811; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PCSK9 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 120/510 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs793888521, CM164687; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- UROC1 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 214/472 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852795, CM093242; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.2513C>T p.P838L | Missense Mutation (SNP) | VAF 214/333 reads (64%) | SIFT tolerated (0.33); PolyPhen benign (0.109); catalogued as rs1464862721; called by muse, mutect2, varscan2
- A2ML1 | c.871T>C p.C291R | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1310248691; called by muse, mutect2, varscan2
- ABCA13 | c.12962C>T p.S4321L | Missense Mutation (SNP) | VAF 87/661 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as COSV68946248; called by muse, mutect2, varscan2
- ABCA4 | c.4001C>T p.P1334L | Missense Mutation (SNP) | VAF 570/776 reads (73%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs770774620; called by muse, mutect2, varscan2
- ABCB1 | c.3517G>A p.G1173R | Missense Mutation (SNP) | VAF 445/633 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473237773; called by muse, mutect2, varscan2
- ABCB1 | c.2702T>A p.I901K | Missense Mutation (SNP) | VAF 63/464 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55952788; called by muse, mutect2, varscan2
- ABCC9 | c.2857G>A p.E953K | Missense Mutation (SNP) | VAF 87/247 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.495); catalogued as rs143685061; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABI3BP | c.2153A>T p.N718I | Missense Mutation (SNP) | VAF 217/480 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV52554053; called by muse, mutect2, varscan2
- ABRAXAS2 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 80/296 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.23); catalogued as rs765356910, COSV100045102; called by muse, mutect2, varscan2
- AC126283.2 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 163/363 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773085612, CM161603, COSV67098504; called by muse, mutect2, varscan2
- ACACB | c.2390C>T p.S797F | Missense Mutation (SNP) | VAF 83/215 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV100623287; called by muse, mutect2, varscan2
- ACACB | c.2821C>T p.R941W | Missense Mutation (SNP) | VAF 116/361 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.846); catalogued as rs780115048; called by muse, mutect2, varscan2
- ACAD11 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 188/376 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53896160; called by muse, mutect2, varscan2
- ACAD11 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 188/375 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV53894922; called by muse, mutect2, varscan2
- ACAN | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 440/440 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV61356492; called by muse, mutect2, varscan2
- ACAN | c.4655G>A p.G1552E | Missense Mutation (SNP) | VAF 176/378 reads (47%) | SIFT tolerated (0.78); PolyPhen benign (0.219); catalogued as COSV61369171; called by muse, mutect2, varscan2
- ACD | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 407/598 reads (68%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.013); catalogued as COSV54665920, COSV99538042; called by muse, mutect2, varscan2
- ACKR1 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 344/443 reads (78%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.684); catalogued as COSV63674515; called by muse, mutect2, varscan2
- ACMSD | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 229/479 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267598885, COSV51606002, COSV51609903; called by muse, mutect2, varscan2
- ACSL3 | c.2041C>T p.R681C | Missense Mutation (SNP) | VAF 200/613 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs776538313, COSV62481117; called by muse, mutect2, varscan2
- ACSL5 | c.407G>A p.G136D (on ENST00000354273; = p.G192D on NM_016234.3) | Missense Mutation (SNP) | VAF 80/295 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866014176; called by muse, varscan2
- ACTR3B | c.225G>A p.K75= | Splice Region (SNP) | VAF 76/343 reads (22%) | catalogued as COSV55450043; called by muse, mutect2, varscan2
- ADAD2 | c.1636G>A p.E546K (on ENST00000315906 / NM_001145400.2; = p.E628K on NM_139174.4) | Missense Mutation (SNP) | VAF 141/378 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.885); catalogued as rs914904996, COSV51894041; called by muse, mutect2, varscan2
- ADAM18 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 235/359 reads (65%) | SIFT tolerated (0.93); PolyPhen benign (0.031); catalogued as COSV55847632; called by muse, mutect2, varscan2
- ADAM29 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 217/437 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs376197978; called by muse, mutect2, varscan2
- ADAM7 | c.1064G>A p.G355E | Missense Mutation (SNP) | VAF 169/252 reads (67%) | SIFT tolerated (0.65); PolyPhen benign (0.04); catalogued as rs768627416, COSV51537798; called by muse, mutect2, varscan2
- ADAM7 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 123/384 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61757471, COSV51536147; called by muse, mutect2, varscan2
- ADAMTS18 | c.2479C>T p.R827C | Missense Mutation (SNP) | VAF 104/395 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs751194192, COSV99274405; called by muse, mutect2, varscan2
- ADAMTS9 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 167/393 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.076); catalogued as rs773453319, COSV55790673; called by muse, mutect2, varscan2
- ADAMTS9 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 149/360 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV55777721, COSV99899601; called by muse, mutect2, varscan2
- ADAMTSL1 | c.5130G>A p.W1710* | Nonsense Mutation (SNP) | VAF 714/717 reads (100%) | catalogued as rs760817930; called by muse, mutect2, varscan2
- ADAMTSL1 | c.5131G>A p.G1711R | Missense Mutation (SNP) | VAF 718/720 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1322321479; called by muse, mutect2, varscan2
- ADCY5 | c.3072G>T p.E1024D | Missense Mutation (SNP) | VAF 143/296 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as COSV59204504; called by muse, mutect2, varscan2
- ADCY5 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 208/409 reads (51%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.187); catalogued as rs1023838544; called by muse, mutect2, varscan2
- ADGRD1 | c.2518C>T p.H840Y | Missense Mutation (SNP) | VAF 74/338 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.022); catalogued as rs1253655764; called by muse, mutect2
- ADGRL2 | c.4058C>T p.S1353F (on ENST00000370717 / NM_001366005.1; = p.S1297F on NM_012302.4) | Missense Mutation (SNP) | VAF 141/574 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV54698050, COSV99046898; called by muse, mutect2, varscan2
- ADGRL3 | c.1120G>A p.D374N (on ENST00000506720 / NM_001322402.2; = p.D306N on NM_015236.6) | Missense Mutation (SNP) | VAF 192/460 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV72269560; called by muse, mutect2, varscan2
- ADGRL4 | c.1213C>T p.H405Y | Missense Mutation (SNP) | VAF 92/431 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66063769; called by muse, mutect2, varscan2
- ADH5 | c.114+1G>A p.X38_splice | Splice Site (SNP) | VAF 166/351 reads (47%) | catalogued as rs370062163; called by muse, mutect2, varscan2
- ADRA2A | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 585/589 reads (99%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV99701897; called by muse, mutect2, varscan2
- AGAP4 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 173/250 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV101432615; called by muse, mutect2, varscan2
- AGO4 | c.2522C>T p.P841L | Missense Mutation (SNP) | VAF 113/412 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1006671149, COSV100942857; called by muse, mutect2, varscan2
- AHNAK | c.12761C>T p.A4254V | Missense Mutation (SNP) | VAF 104/598 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV99945871; called by muse, mutect2, varscan2
- AHNAK2 | c.13049C>T p.P4350L | Missense Mutation (SNP) | VAF 173/559 reads (31%) | SIFT tolerated (0.97); PolyPhen benign (0.022); catalogued as rs775570955; called by muse, mutect2, varscan2
- AHNAK2 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 298/802 reads (37%) | catalogued as rs1188646569, COSV60912557; called by muse, varscan2
- AHSP | c.211C>T p.R71W | Missense Mutation (SNP) | VAF 288/443 reads (65%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV56528664; called by muse, mutect2, varscan2
- AKAIN1 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as rs1189292467; called by muse, mutect2, varscan2
- AKAP3 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 168/249 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1345037350, COSV57420026; called by muse, mutect2, varscan2
- AKNA | c.3143C>T p.P1048L | Missense Mutation (SNP) | VAF 346/522 reads (66%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV56337188; called by muse, mutect2, varscan2
- AL592490.1 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 102/402 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV101308241; called by muse, mutect2, varscan2
- AL592490.1 | c.785A>G p.E262G | Missense Mutation (SNP) | VAF 126/477 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs751267885, COSV69427512; called by muse, mutect2, varscan2
- AL592490.1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 130/475 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV69426761; called by muse, mutect2, varscan2
- ALB | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 158/349 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs774294755, COSV55738750, COSV55739357; called by muse, mutect2, varscan2
- ALDH1L1 | c.897G>A p.M299I | Missense Mutation (SNP) | VAF 126/293 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.692); catalogued as COSV56412707; called by muse, mutect2, varscan2
- ALG8 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 95/378 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748962880, CM098505; called by muse, mutect2, varscan2
- ALS2 | c.4270C>T p.Q1424* | Nonsense Mutation (SNP) | VAF 142/298 reads (48%) | catalogued as COSV51885932, COSV51888690; called by muse, mutect2, varscan2
- AMY1C | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 81/597 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1203608595; called by muse, mutect2, varscan2
- ANGEL1 | c.1081C>T p.R361W | Missense Mutation (SNP) | VAF 385/663 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs546885277; called by muse, mutect2, varscan2
- ANHX | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 219/325 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV69293514, COSV69294039; called by muse, mutect2, varscan2
- ANK1 | c.4577C>T p.S1526F | Missense Mutation (SNP) | VAF 102/323 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.581); catalogued as rs777979057; called by muse, mutect2, varscan2
- ANK2 | c.1894C>T p.P632S | Missense Mutation (SNP) | VAF 130/294 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1327848108, COSV52183131; called by muse, mutect2, varscan2
- ANK3 | c.13130C>T p.S4377L (on ENST00000280772 / NM_001320874.2; = p.S1001L on NM_001149.3) | Missense Mutation (SNP) | VAF 279/280 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); catalogued as rs201169886; called by muse, mutect2, varscan2
- ANK3 | c.8686G>A p.E2896K | Missense Mutation (SNP) | VAF 212/339 reads (63%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as COSV55073735; called by muse, mutect2, varscan2
- ANKEF1 | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 95/411 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV65693696; called by muse, mutect2, varscan2
- ANKEF1 | c.2278C>T p.Q760* | Nonsense Mutation (SNP) | VAF 98/455 reads (22%) | catalogued as rs763362315; called by muse, mutect2, varscan2
- ANKRD11 | c.6164C>T p.P2055L | Missense Mutation (SNP) | VAF 181/587 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.348); catalogued as rs1281426768; called by muse, mutect2, varscan2
- ANKRD18A | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 314/595 reads (53%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as rs528054598, COSV68803926; called by muse, mutect2, varscan2
- ANKRD30B | c.1570G>T p.E524* | Nonsense Mutation (SNP) | VAF 41/98 reads (42%) | catalogued as COSV62813745; called by muse, mutect2, varscan2
- ANKRD33 | c.61C>T p.L21F (on ENST00000340970 / NM_001304459.2; = p.L156F on NM_182608.4) | Missense Mutation (SNP) | VAF 251/413 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1331722896; called by muse, mutect2, varscan2
- ANKRD35 | c.1554G>A p.M518I | Missense Mutation (SNP) | VAF 279/555 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.038); catalogued as rs781970487, COSV100841732; called by muse, mutect2, varscan2
- ANKRD7 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 100/461 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV54554663; called by muse, mutect2, varscan2
- ANO3 | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 125/490 reads (26%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.998); catalogued as COSV56805536; called by muse, mutect2, varscan2
- ANO4 | c.2708C>T p.S903L (on ENST00000392977 / NM_001286615.2; = p.S868L on NM_178826.4) | Missense Mutation (SNP) | VAF 192/304 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV54587306; called by muse, varscan2
- ANO4 | c.2840G>A p.G947E (on ENST00000392977 / NM_001286615.2; = p.G912E on NM_178826.4) | Missense Mutation (SNP) | VAF 204/328 reads (62%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.821); catalogued as COSV100153120; called by muse, varscan2
- ANXA10 | c.63G>A p.M21I | Missense Mutation (SNP) | VAF 238/521 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as COSV63740390; called by muse, mutect2, varscan2
- AP4E1 | c.2663C>T p.P888L | Missense Mutation (SNP) | VAF 443/443 reads (100%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV99956779; called by muse, mutect2, varscan2
- APLF | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 259/494 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV58143985; called by muse, mutect2, varscan2
- APOB | c.10918C>T p.H3640Y | Missense Mutation (SNP) | VAF 267/516 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV51956078; called by muse, mutect2, varscan2
- APOB | c.3814C>T p.H1272Y | Missense Mutation (SNP) | VAF 139/328 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV51958098; called by muse, mutect2, varscan2
- APOOL | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 225/225 reads (100%) | catalogued as rs1166452268; called by muse, mutect2, varscan2
- ARAP2 | c.3074A>T p.D1025V | Missense Mutation (SNP) | VAF 199/427 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1206789876; called by muse, mutect2, varscan2
- ARAP2 | c.2999A>G p.K1000R | Missense Mutation (SNP) | VAF 122/245 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1233247869; called by muse, mutect2, varscan2
- ARAP2 | c.2083G>A p.E695K | Missense Mutation (SNP) | VAF 220/449 reads (49%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.956); catalogued as COSV100394605, COSV58287024; called by muse, mutect2, varscan2
- ARFGEF3 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 196/439 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs375082443; called by muse, varscan2
- ARFGEF3 | c.3481G>A p.D1161N | Missense Mutation (SNP) | VAF 169/359 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.194); catalogued as rs771752189, COSV52466521; called by muse, mutect2, varscan2
- ARHGAP21 | c.2527C>T p.P843S | Missense Mutation (SNP) | VAF 360/362 reads (99%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV57612113; called by muse, mutect2, varscan2
- ARHGAP26 | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 95/339 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50829120; called by muse, mutect2, varscan2
- ARHGAP32 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV59855612; called by muse, mutect2, varscan2
- ARHGEF17 | c.4651C>T p.L1551F | Missense Mutation (SNP) | VAF 151/655 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1415397584; called by muse, mutect2, varscan2
- ARHGEF7 | c.1791C>T p.L597= (on ENST00000375741 / NM_001113511.2; = p.L419= on NM_003899.5 and 5 other RefSeq transcripts) | Splice Region (SNP) | VAF 121/458 reads (26%) | catalogued as rs1164951891; called by muse, mutect2, varscan2
- ARID1B | c.3099G>A p.K1033= | Splice Region (SNP) | VAF 108/242 reads (45%) | catalogued as rs373653398; called by muse, mutect2, varscan2
- ARID2 | c.1363C>T p.Q455* | Nonsense Mutation (SNP) | VAF 204/303 reads (67%) | catalogued as rs994352749; called by muse, mutect2, varscan2
- ARID5B | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 398/400 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV54430683; called by muse, mutect2, varscan2
- ARMC2 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 298/591 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs138386250; called by muse, mutect2, varscan2
- ARRDC5 | c.593C>T p.T198I (on ENST00000381781; = p.T184I on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/413 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV67788344; called by muse, mutect2, varscan2
- ARSH | c.1432G>A p.D478N | Missense Mutation (SNP) | VAF 89/313 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.077); catalogued as rs759497002, COSV66962565; called by muse, mutect2, varscan2
- ASB17 | c.47G>A p.S16N | Missense Mutation (SNP) | VAF 67/368 reads (18%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.162); catalogued as COSV52412040; called by muse, mutect2, varscan2
- ASH2L | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 199/662 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.013); catalogued as rs1401405242; called by muse, mutect2, varscan2
- ASIC4 | c.451C>A p.R151S | Missense Mutation (SNP) | VAF 325/999 reads (33%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.742); catalogued as rs771952448, COSV61731676; called by muse, mutect2, varscan2
- ASTN1 | c.3623G>A p.R1208Q | Missense Mutation (SNP) | VAF 251/329 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768973979, COSV62496507; called by muse, mutect2, varscan2
- ASTN1 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 202/399 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs763391667, COSV56064196; called by muse, varscan2
- ASTN1 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 90/518 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs775782427, COSV56062768; called by muse, varscan2
- ATF6B | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 283/543 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV64351243; called by muse, mutect2, varscan2
- ATM | c.8978G>A p.R2993Q | Missense Mutation (SNP) | VAF 94/348 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs587778081, CX002572, COSV53733041; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- ATN1 | c.2486_2503del p.R829_E834del | In Frame Del (DEL) | VAF 126/274 reads (46%) | catalogued as rs1367398901; called by mutect2, varscan2
- ATP1A4 | c.2750G>A p.R917Q | Missense Mutation (SNP) | VAF 83/360 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs764509935; called by muse, mutect2, varscan2
- ATP2A1 | c.2183A>G p.K728R | Missense Mutation (SNP) | VAF 155/397 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs747116287; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP2A3 | c.2171C>A p.T724K | Missense Mutation (SNP) | VAF 535/538 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99989038; called by muse, mutect2, varscan2
- ATP2B2 | c.2266C>T p.R756C (on ENST00000352432; = p.R722C on NM_001683.5) | Missense Mutation (SNP) | VAF 140/336 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs762199117, COSV100660016; called by muse, varscan2
- ATP2C2 | c.1831G>A p.G611R | Missense Mutation (SNP) | VAF 94/239 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV52293969; called by muse, mutect2, varscan2
- ATP8A1 | c.2486C>T p.S829F | Missense Mutation (SNP) | VAF 164/373 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs267600160, COSV52529896; called by muse, mutect2, varscan2
- ATRNL1 | c.3728C>T p.S1243F | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100371101, COSV58089242; called by muse, mutect2, varscan2
- B3GAT2 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 113/258 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1367932495; called by muse, mutect2, varscan2
- B3GNT8 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 300/449 reads (67%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs769165524; called by muse, mutect2, varscan2
- BARD1 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 233/735 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs758368819, COSV53611819; called by muse, mutect2, varscan2
- BCAR1 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 240/722 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs751244629; called by muse, mutect2, varscan2
- BCL11A | c.1885T>C p.Y629H (on ENST00000335712 / NM_001365609.1; = p.Y663H on NM_018014.4) | Missense Mutation (SNP) | VAF 377/692 reads (54%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1227579541; called by muse, mutect2, varscan2
- BCORL1 | c.1162C>T p.P388S | Missense Mutation (SNP) | VAF 515/792 reads (65%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.725); catalogued as rs754043220; called by muse, varscan2
- BCR | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 204/403 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs1337299573, COSV59928527; called by muse, mutect2, varscan2
- BEST3 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 280/405 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748231464, COSV56994383; called by muse, mutect2, varscan2
- BMPER | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 152/539 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.383); catalogued as rs1228099396, COSV51814331; called by muse, mutect2, varscan2
- BNIPL | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 64/313 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs201384045, COSV54848559; called by muse, mutect2, varscan2
- BPIFB2 | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 143/635 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99401755; called by muse, mutect2, varscan2
- BPIFB4 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 299/414 reads (72%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.878); catalogued as rs535736291, COSV64951283; called by muse, mutect2, varscan2
- BRCA2 | c.6628G>A p.E2210K | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV66451327; called by muse, mutect2, varscan2
- BRD2 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 229/490 reads (47%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.695); catalogued as COSV66373056; called by muse, mutect2, varscan2
- BRDT | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 95/413 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs760550779, COSV62866557; called by muse, mutect2, varscan2
- BRINP3 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 302/400 reads (76%) | SIFT tolerated (0.23); PolyPhen benign (0.147); catalogued as rs375567534, COSV66538726; called by muse, varscan2
- C11orf95 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 143/695 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1244411958; called by muse, mutect2, varscan2
- C12orf50 | c.505A>G p.K169E | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100072436; called by muse, mutect2, varscan2
- C14orf180 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 301/518 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100118822, COSV99045674; called by muse, mutect2, varscan2
- C1QTNF9 | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217238221; called by muse, mutect2, varscan2
- C1S | c.1466C>T p.S489F | Missense Mutation (SNP) | VAF 232/346 reads (67%) | SIFT tolerated (0.17); PolyPhen benign (0.37); catalogued as COSV100196394; called by muse, mutect2, varscan2
- C1orf115 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 246/325 reads (76%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs763806580; called by muse, mutect2, varscan2
- C1orf162 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 116/436 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.234); catalogued as COSV100636254; called by muse, mutect2, varscan2
- C20orf203 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 142/619 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs912334584; called by muse, mutect2, varscan2
- C2orf80 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 158/460 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV58017201; called by muse, mutect2, varscan2
- C3orf20 | c.1591G>A p.D531N | Missense Mutation (SNP) | VAF 181/402 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.876); catalogued as COSV104389297; called by muse, mutect2, varscan2
- C6orf15 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 398/857 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as COSV99456658; called by muse, mutect2, varscan2
- C7orf61 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 617/922 reads (67%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1433498181; called by muse, mutect2, varscan2
- C9 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 220/350 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767572697; called by muse, mutect2, varscan2
- CACNA1B | c.3760C>T p.R1254C | Missense Mutation (SNP) | VAF 416/416 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1294351388; called by muse, varscan2
- CACNA1B | c.6872C>T p.S2291F | Missense Mutation (SNP) | VAF 534/953 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs1222036403, COSV53123101; called by muse, mutect2, varscan2
- CACNA1C | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 335/491 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs1027539784, COSV59702441; called by muse, mutect2, varscan2
- CACNA1E | c.2933C>T p.A978V | Missense Mutation (SNP) | VAF 64/295 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV62405524, COSV62408644; called by muse, mutect2, varscan2
- CACNA1H | c.6188G>A p.R2063Q | Missense Mutation (SNP) | VAF 422/642 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs866288176, COSV52353044; called by muse, mutect2, varscan2
- CADPS | c.3742G>A p.V1248I | Missense Mutation (SNP) | VAF 147/338 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs751860249, COSV99340661; called by muse, mutect2, varscan2
- CADPS | c.2836G>A p.D946N | Missense Mutation (SNP) | VAF 214/459 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.15); catalogued as COSV99338789; called by muse, mutect2, varscan2
- CADPS2 | c.2530G>A p.A844T | Missense Mutation (SNP) | VAF 74/607 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.74); catalogued as rs867582496; called by muse, mutect2, varscan2
- CAMSAP3 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 755/757 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs1384777444; called by muse, mutect2, varscan2
- CAPN14 | c.1856G>A p.G619E | Missense Mutation (SNP) | VAF 112/213 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs1176667390; called by muse, mutect2
- CAPN8 | c.1891A>G p.R631G | Missense Mutation (SNP) | VAF 145/555 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1187698743; called by muse, mutect2, varscan2
- CARD18 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 230/466 reads (49%) | SIFT tolerated (0.85); PolyPhen benign (0.326); catalogued as COSV101596041; called by muse, mutect2, varscan2
- CASP8 | c.883A>G p.I295V (on ENST00000432109 / NM_033355.3; = p.I312V on NM_001228.4) | Missense Mutation (SNP) | VAF 16/576 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs979257464, COSV51847064; called by muse, mutect2
- CBL | c.1096-1G>A p.X366_splice | Splice Site (SNP) | VAF 104/135 reads (77%) | catalogued as CD1314297, CS099550, CS150637, COSV50631547, COSV50635311, COSV50641081; called by muse, mutect2, varscan2
- CBL | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 108/140 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1245863855, COSV50657369, COSV50665310; called by muse, mutect2, varscan2
- CCDC110 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 74/231 reads (32%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.769); catalogued as COSV100294059, COSV56869319; called by muse, mutect2, varscan2
- CCDC141 | c.2912C>T p.S971F | Missense Mutation (SNP) | VAF 121/278 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV55369638; called by muse, mutect2, varscan2
- CCDC141 | c.2494G>A p.E832K | Missense Mutation (SNP) | VAF 278/506 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs769268802, COSV55371354; called by muse, mutect2, varscan2
- CCDC158 | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 253/484 reads (52%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as rs370067451; called by muse, mutect2, varscan2
- CCDC168 | c.16708A>T p.T5570S | Missense Mutation (SNP) | VAF 363/522 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as COSV100487593; called by muse, mutect2, varscan2
- CCDC168 | c.12136G>A p.E4046K | Missense Mutation (SNP) | VAF 75/312 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.281); catalogued as COSV59421924; called by muse, mutect2, varscan2
- CCDC175 | c.1352G>A p.R451K | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs1174365842, COSV55786932; called by muse, mutect2
- CCDC3 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 232/232 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV101121771, COSV66558838; called by muse, mutect2, varscan2
- CCDC68 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as COSV61604679; called by muse, mutect2, varscan2
- CCDC88B | c.2318G>A p.R773Q | Missense Mutation (SNP) | VAF 275/542 reads (51%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.559); catalogued as rs970377728; called by muse, mutect2, varscan2
- CCL26 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 419/615 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs782727471; called by muse, mutect2, varscan2
- CCNB3 | c.2030C>T p.S677L | Missense Mutation (SNP) | VAF 111/407 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); catalogued as COSV99329927; called by muse, mutect2, varscan2
- CCR2 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 200/449 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52750465; called by muse, mutect2, varscan2
- CD109 | c.3650C>T p.P1217L | Missense Mutation (SNP) | VAF 223/471 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV99754282; called by muse, mutect2, varscan2
- CD164 | c.330C>T p.S110= | Splice Region (SNP) | VAF 130/317 reads (41%) | catalogued as rs199887608; ClinVar: likely benign; called by muse, mutect2, varscan2
- CD200R1L | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 193/402 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68004516; called by muse, mutect2, varscan2
- CD276 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 180/415 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.289); catalogued as rs1320456567; called by muse, mutect2, varscan2
- CD300E | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 240/639 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs1250703050, COSV60791455; called by muse, mutect2, varscan2
- CD40 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as rs1406703700; called by muse, mutect2, varscan2
- CDH12 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 293/297 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66390362; called by muse, mutect2, varscan2
- CDH12 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 255/255 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs945820536, COSV101200656, COSV66455223; called by muse, mutect2, varscan2
- CDH17 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 243/383 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as rs868699389; called by muse, mutect2, varscan2
- CDH8 | c.2077G>A p.G693R | Missense Mutation (SNP) | VAF 171/471 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.105); catalogued as rs867793640, COSV54905377; called by muse, mutect2, varscan2
- CDON | c.1724C>T p.S575F | Missense Mutation (SNP) | VAF 148/304 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs758713160; called by muse, mutect2, varscan2
- CEACAM8 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 245/246 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.424); catalogued as rs985625692, COSV99747478; called by muse, mutect2, varscan2
- CELSR1 | c.6115C>T p.P2039S | Missense Mutation (SNP) | VAF 219/455 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs753225249; called by muse, mutect2, varscan2
- CELSR2 | c.4333G>A p.G1445R | Missense Mutation (SNP) | VAF 183/343 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs753290065, COSV54775550; called by muse, mutect2, varscan2
- CERS6 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 229/454 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV59836181; called by muse, mutect2, varscan2
- CES3 | c.92T>C p.V31A | Missense Mutation (SNP) | VAF 97/311 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1292970444; called by muse, varscan2
- CETN2 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 198/306 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs782779595, COSV64743193; called by muse, varscan2
- CFAP43 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 205/283 reads (72%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs750966857; called by muse, mutect2, varscan2
- CFAP54 | c.5975G>A p.G1992E | Missense Mutation (SNP) | VAF 86/262 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1478385976; called by muse, mutect2, varscan2
- CFAP65 | c.4639G>A p.E1547K | Missense Mutation (SNP) | VAF 253/694 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs1172470608; called by muse, mutect2, varscan2
- CFAP65 | c.3166C>T p.P1056S | Missense Mutation (SNP) | VAF 210/629 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.099); catalogued as COSV58563788; called by muse, mutect2, varscan2
- CFHR4 | c.1591G>A p.G531R (on ENST00000367416 / NM_001201551.2; = p.G285R on NM_006684.5) | Missense Mutation (SNP) | VAF 86/116 reads (74%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.482); catalogued as COSV52226308; called by muse, mutect2, varscan2
- CFP | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 157/458 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.409); catalogued as COSV55950992; called by muse, mutect2, varscan2
- CGNL1 | c.3286G>A p.E1096K | Missense Mutation (SNP) | VAF 144/305 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as rs770839772; called by muse, mutect2, varscan2
- CHRNA1 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 244/590 reads (41%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as rs146743352, COSV53682258; called by muse, mutect2, varscan2
- CHRNA2 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 307/476 reads (64%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.773); catalogued as rs774054592, COSV53557297; called by muse, mutect2, varscan2
- CHRNA6 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 103/289 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as rs772665574; called by muse, mutect2, varscan2
- CIC | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 444/444 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.268); catalogued as COSV50568090, COSV99360207; called by muse, mutect2, varscan2
- CLASP1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 224/480 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746501087, COSV55321894; called by muse, mutect2, varscan2
- CLCN2 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 198/425 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs752010877; called by muse, mutect2, varscan2
- CLDN14 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 128/605 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59775955; called by muse, mutect2, varscan2
- CLDN18 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 219/443 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs768414784, COSV51738820; called by muse, mutect2, varscan2
- CLEC6A | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.066); catalogued as COSV65987455; called by muse, mutect2, varscan2
- CLIP4 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 182/388 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as COSV60750830; called by muse, mutect2, varscan2
- CLSTN2 | c.2083G>C p.D695H | Missense Mutation (SNP) | VAF 88/393 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1329618210, COSV71718337; called by muse, mutect2, varscan2
- CMAS | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 178/258 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs372322273; called by muse, mutect2, varscan2
- CMYA5 | c.4711C>T p.P1571S | Missense Mutation (SNP) | VAF 111/444 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV71410414; called by muse, mutect2, varscan2
- CNGB3 | c.2201G>A p.G734E | Missense Mutation (SNP) | VAF 250/354 reads (71%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs757799031, COSV60686027, COSV60687783; called by muse, mutect2, varscan2
- CNPY1 | c.64G>A p.E22K (on ENST00000636446; = p.E3K on NM_001369813.1) | Missense Mutation (SNP) | VAF 88/658 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1368450100; called by muse, mutect2, varscan2
- CNTN5 | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 104/484 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.345); catalogued as rs1317730113, COSV54355612; called by muse, mutect2, varscan2
- CNTN5 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 97/361 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54285866; called by muse, mutect2, varscan2
- CNTNAP2 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 278/674 reads (41%) | catalogued as COSV62156912; called by muse, mutect2, varscan2
- COL11A1 | c.3254C>T p.P1085L | Missense Mutation (SNP) | VAF 78/381 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV62179994; called by muse, mutect2, varscan2
- COL14A1 | c.3919G>A p.E1307K | Missense Mutation (SNP) | VAF 83/278 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52847444; called by muse, mutect2, varscan2
- COL1A2 | c.1423G>A p.G475S | Missense Mutation (SNP) | VAF 137/842 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755058199, COSV51954646; called by muse, mutect2
- COL1A2 | c.2324G>A p.G775E | Missense Mutation (SNP) | VAF 504/704 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51957336; called by muse, mutect2, varscan2
- COL21A1 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 162/350 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55155492; called by muse, mutect2, varscan2
- COL21A1 | c.1013A>G p.N338S | Missense Mutation (SNP) | VAF 117/252 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV55172173; called by muse, mutect2, varscan2
- COL22A1 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 222/331 reads (67%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.857); catalogued as rs778667471, COSV57325080; called by muse, varscan2
- COL27A1 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 261/377 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV61927749; called by muse, mutect2, varscan2
- COL4A3 | c.3864G>A p.M1288I | Missense Mutation (SNP) | VAF 149/498 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV59258193; called by muse, mutect2, varscan2
- COL4A4 | c.3665C>T p.P1222L | Missense Mutation (SNP) | VAF 204/680 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs377230950; called by muse, mutect2, varscan2
- COL4A5 | c.3266G>A p.G1089E | Missense Mutation (SNP) | VAF 167/259 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM115545; called by muse, mutect2, varscan2
- COL5A1 | c.2350G>A p.G784S | Missense Mutation (SNP) | VAF 411/412 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767627080, COSV100880585; called by muse, mutect2, varscan2
- COL5A2 | c.2608G>A p.G870R | Missense Mutation (SNP) | VAF 169/356 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66413060; called by muse, mutect2, varscan2
- COL6A1 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 92/446 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.07); catalogued as rs1483485124; called by mutect2, varscan2
- COL6A3 | c.8021C>T p.S2674F | Missense Mutation (SNP) | VAF 557/823 reads (68%) | SIFT tolerated (0.7); PolyPhen benign (0.339); catalogued as rs1169456064, COSV55110075; called by muse, mutect2, varscan2
- COL6A3 | c.6460C>T p.R2154* | Nonsense Mutation (SNP) | VAF 166/541 reads (31%) | catalogued as rs762768377, COSV104402597, COSV55079291; called by muse, mutect2, varscan2
- COL6A3 | c.4649G>A p.G1550E | Missense Mutation (SNP) | VAF 659/990 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV55078348; called by muse, mutect2, varscan2
- COL6A5 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 232/492 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs976274616, COSV55208289; called by muse, mutect2, varscan2
- COL7A1 | c.8776G>A p.E2926K | Missense Mutation (SNP) | VAF 336/713 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV56476438; called by muse, mutect2, varscan2
- COL8A2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 171/689 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.646); catalogued as rs776813844, COSV57442924; called by muse, mutect2, varscan2
- COL9A1 | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 146/291 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753682260, COSV100294120, COSV57893257; called by muse, mutect2, varscan2
- COLEC10 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 71/221 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1215289749; called by muse, mutect2, varscan2
- COMMD6 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 74/276 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.416); catalogued as COSV100869867; called by muse, mutect2, varscan2
- COMMD8 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 265/564 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.978); catalogued as rs1466358636, COSV67500322; called by muse, mutect2, varscan2
- COPS7A | c.655A>C p.T219P | Missense Mutation (SNP) | VAF 93/284 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV57527080; called by muse, mutect2, varscan2
- CPA3 | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 171/373 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as rs1458791547; called by muse, mutect2, varscan2
- CPN1 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 210/339 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs908037906, COSV64941879; called by muse, mutect2, varscan2
- CPXM2 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 221/656 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as rs1217291885, COSV53867392; called by muse, mutect2, varscan2
- CR2 | c.2606G>A p.R869Q | Missense Mutation (SNP) | VAF 259/371 reads (70%) | SIFT tolerated (0.38); PolyPhen benign (0.188); catalogued as rs756989345, COSV100889697; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRYBG1 | c.2653C>T p.P885S | Missense Mutation (SNP) | VAF 222/408 reads (54%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.02); catalogued as COSV64814026; called by muse, mutect2, varscan2
- CRYBG1 | c.5966G>A p.R1989Q | Missense Mutation (SNP) | VAF 124/260 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs753275483, COSV64811380; called by muse, mutect2, varscan2
- CSMD1 | c.10370G>A p.G3457E (on ENST00000520002; = p.G3456E on NM_033225.6) | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV59301362; called by muse, mutect2, varscan2
- CSMD1 | c.6371C>T p.P2124L (on ENST00000520002; = p.P2123L on NM_033225.6) | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59293363; called by muse, mutect2, varscan2
- CSMD1 | c.5612G>A p.G1871E (on ENST00000520002; = p.G1870E on NM_033225.6) | Missense Mutation (SNP) | VAF 76/284 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761601416, COSV59299434; called by muse, mutect2, varscan2
- CSMD1 | c.3142G>A p.D1048N (on ENST00000520002; = p.D1047N on NM_033225.6) | Missense Mutation (SNP) | VAF 80/276 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59282193; called by muse, mutect2, varscan2
- CSMD1 | c.3089C>T p.S1030L (on ENST00000520002; = p.S1029L on NM_033225.6) | Missense Mutation (SNP) | VAF 208/332 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs773842728, COSV59282220; called by muse, mutect2
- CSMD1 | c.2329G>A p.G777R (on ENST00000520002; = p.G776R on NM_033225.6) | Missense Mutation (SNP) | VAF 97/322 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1184130564; called by muse, mutect2, varscan2
- CSMD2 | c.9232C>T p.R3078C | Missense Mutation (SNP) | VAF 334/445 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1283736318, COSV53915658, COSV53961019; called by muse, mutect2, varscan2
- CSMD2 | c.6764G>A p.S2255N | Missense Mutation (SNP) | VAF 108/510 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs201941971; called by muse, mutect2, varscan2
- CSMD2 | c.1228C>T p.R410* | Nonsense Mutation (SNP) | VAF 91/413 reads (22%) | catalogued as rs775939532, COSV53891554; called by muse, mutect2, varscan2
- CSMD3 | c.9172G>A p.D3058N (on ENST00000297405 / NM_001363185.1; = p.D2889N on NM_052900.3) | Missense Mutation (SNP) | VAF 88/280 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.443); catalogued as rs759864023, COSV52105606, COSV52257196; called by muse, varscan2
- CSN2 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 266/571 reads (47%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.462); catalogued as rs753388171; called by muse, mutect2, varscan2
- CTAGE1 | c.1544G>A p.R515K | Missense Mutation (SNP) | VAF 102/173 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs1308824372; called by muse, mutect2, varscan2
- CTAGE15 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 162/355 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs757722933, COSV69481949; called by muse, mutect2, varscan2
- CTAGE8 | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 237/462 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.602); catalogued as COSV100966767; called by muse, mutect2, varscan2
- CTAGE9 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 118/523 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs1430254029, COSV100020665; called by muse, mutect2, varscan2
- CUL4A | c.1768C>T p.Q590* (on ENST00000375440 / NM_001008895.4; = p.Q490* on NM_003589.3) | Nonsense Mutation (SNP) | VAF 68/248 reads (27%) | catalogued as COSV58376449; called by muse, mutect2, varscan2
- CXCR5 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 146/681 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs149961413; called by muse, mutect2, varscan2
- CYP1A2 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 196/461 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1389226935; called by muse, mutect2, varscan2
- CYP2C18 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 125/126 reads (99%) | SIFT tolerated (0.18); PolyPhen benign (0.341); catalogued as COSV53670127; called by muse, mutect2, varscan2
- CYP2C19 | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 314/314 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV64909219; called by muse, mutect2, varscan2
- CYP2C8 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 168/168 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as CM115008, COSV64878951; called by muse, varscan2
- CYP3A7 | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 74/555 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220927730, COSV60480780; called by muse, mutect2, varscan2
- DAAM2 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 233/470 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV51373392; called by muse, mutect2, varscan2
- DACH1 | c.1720G>A p.E574K (on ENST00000619232 / NM_001366712.1; = p.E522K on NM_080759.6) | Missense Mutation (SNP) | VAF 167/228 reads (73%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV57498706, COSV57499795; called by muse, varscan2
- DAGLA | c.677T>A p.F226Y | Missense Mutation (SNP) | VAF 109/426 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1199338512; called by muse, mutect2, varscan2
- DBH | c.1808G>A p.S603N | Missense Mutation (SNP) | VAF 279/418 reads (67%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.107); catalogued as rs1200124192; called by muse, mutect2, varscan2
- DCAF4L2 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 220/386 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as rs868106740, COSV60477762, COSV60480991; called by muse, mutect2, varscan2
- DCAF5 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 213/619 reads (34%) | catalogued as COSV58459615; called by muse, mutect2, varscan2
- DCC | c.2114G>A p.G705E | Missense Mutation (SNP) | VAF 120/232 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs191508830; called by muse, mutect2, varscan2
- DDHD2 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 166/266 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs754907740; called by muse, mutect2, varscan2
- DDIAS | c.2620C>T p.P874S | Missense Mutation (SNP) | VAF 300/405 reads (74%) | SIFT tolerated (0.4); PolyPhen benign (0.073); catalogued as rs1481559101, COSV61273578; called by muse, mutect2, varscan2
- DDX25 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 76/127 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs373696148; called by muse, mutect2, varscan2
- DDX51 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 103/315 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs1192145074, COSV57957539; called by muse, mutect2, varscan2
- DENND1B | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 232/330 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753673713; called by muse, mutect2, varscan2
- DENND2A | c.2993G>A p.G998E | Missense Mutation (SNP) | VAF 369/555 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52060421; called by muse, mutect2, varscan2
- DENND3 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 350/579 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52802920; called by muse, mutect2, varscan2
- DHRS4 | c.148C>T p.R50W | Missense Mutation (SNP) | VAF 226/533 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs772524465, COSV57481451; called by muse, varscan2
- DHRS9 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 256/528 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs749731465; called by muse, mutect2, varscan2
- DIABLO | c.320C>T p.S107F (on ENST00000443649 / NM_001278303.1; = p.S180F on NM_019887.6) | Missense Mutation (SNP) | VAF 141/218 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767109973; called by muse, mutect2, varscan2
- DIO3 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 402/1084 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63773286; called by muse, mutect2, varscan2
- DIP2B | c.2482A>G p.I828V | Missense Mutation (SNP) | VAF 119/361 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as rs562083624; called by muse, mutect2, varscan2
- DISP3 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 562/768 reads (73%) | catalogued as rs781482486, COSV53822569; called by muse, mutect2, varscan2
- DISP3 | c.3814G>A p.E1272K | Missense Mutation (SNP) | VAF 224/450 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.05); catalogued as rs774307670, COSV53834694; called by muse, mutect2, varscan2
- DLEC1 | c.2872C>T p.P958S | Missense Mutation (SNP) | VAF 143/313 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as rs777861082; called by muse, mutect2, varscan2
- DMBX1 | c.833A>G p.N278S | Missense Mutation (SNP) | VAF 595/798 reads (75%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs758576876; called by muse, mutect2, varscan2
- DMC1 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 165/319 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201014421, COSV53258054; called by muse, mutect2, varscan2
- DMD | c.8188G>A p.G2730R | Missense Mutation (SNP) | VAF 94/291 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as COSV58891776; called by muse, mutect2, varscan2
- DMRT2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 443/1149 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.035); catalogued as rs866098197; called by muse, mutect2, varscan2
- DNAAF5 | c.1408C>A p.P470T | Missense Mutation (SNP) | VAF 469/1174 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV52416339; called by muse, varscan2
- DNAH10 | c.1018G>A p.E340K (on ENST00000409039; = p.E279K on NM_207437.3) | Missense Mutation (SNP) | VAF 224/339 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69000080; called by muse, mutect2, varscan2
- DNAH10 | c.7870C>T p.R2624* (on ENST00000409039; = p.R2563* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 438/654 reads (67%) | catalogued as rs1021332828, COSV101292108; called by muse, mutect2, varscan2
- DNAH11 | c.9212C>T p.P3071L | Missense Mutation (SNP) | VAF 115/887 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs1216148023; called by muse, mutect2, varscan2
- DNAH12 | c.2255G>A p.R752Q | Missense Mutation (SNP) | VAF 152/370 reads (41%) | SIFT tolerated (0.66); PolyPhen benign (0.015); catalogued as rs775309505; called by muse, mutect2, varscan2
- DNAH12 | c.1690C>G p.L564V | Missense Mutation (SNP) | VAF 144/329 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV61065714; called by muse, mutect2, varscan2
- DNAH12 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 144/373 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1006370903, COSV60855640, COSV60856070; called by muse, mutect2, varscan2
- DNAH14 | c.8846-1G>A p.X2949_splice | Splice Site (SNP) | VAF 140/281 reads (50%) | catalogued as rs1163826712; called by muse, mutect2, varscan2
- DNAH14 | c.9700G>A p.E3234K (on ENST00000445597; = p.E4242K on NM_001367479.1) | Missense Mutation (SNP) | VAF 200/266 reads (75%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.875); catalogued as COSV59900784; called by muse, mutect2, varscan2
- DNAH2 | c.3208G>A p.E1070K | Missense Mutation (SNP) | VAF 476/477 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as COSV101209368; called by muse, mutect2, varscan2
- DNAH3 | c.6371G>A p.R2124Q | Missense Mutation (SNP) | VAF 236/361 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776382752, COSV54515852; called by muse, mutect2, varscan2
- DNAH6 | c.10343G>A p.G3448E | Missense Mutation (SNP) | VAF 103/195 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV52877167; called by muse, mutect2, varscan2
- DNAH7 | c.10760C>T p.A3587V | Missense Mutation (SNP) | VAF 203/435 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56788953; called by muse, mutect2, varscan2
- DNAH8 | c.11195G>A p.R3732K | Missense Mutation (SNP) | VAF 120/244 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59426940; called by muse, mutect2, varscan2
- DNAJC13 | c.3205C>T p.R1069W | Missense Mutation (SNP) | VAF 157/318 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53445460; called by muse, mutect2, varscan2
- DNAJC16 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 106/470 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.232); catalogued as rs765366404; called by muse, mutect2, varscan2
- DOCK9 | c.506C>T p.S169F (on ENST00000376460 / NM_001366676.2; = p.S170F on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 225/337 reads (67%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs201914404; called by muse, mutect2, varscan2
- DRC7 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 109/311 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as rs763592940, COSV61054724; called by muse, mutect2
- DSCAM | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 124/488 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as rs369442382, COSV101260693; called by muse, mutect2, varscan2
- DSE | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 246/502 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100528597; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1367C>T p.S456L | Missense Mutation (SNP) | VAF 125/559 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.074); catalogued as rs769670477, COSV50050996; called by muse, mutect2, varscan2
- DUXA | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 180/282 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs958200676; called by muse, mutect2, varscan2
- DVL3 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 366/789 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); catalogued as rs770741192; called by muse, mutect2, varscan2
- DYSF | c.3294G>A p.M1098I | Missense Mutation (SNP) | VAF 119/729 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); catalogued as COSV50491773; called by muse, mutect2, varscan2
- DYSF | c.5318C>T p.P1773L | Missense Mutation (SNP) | VAF 323/619 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV50302694; called by muse, mutect2, varscan2
- EBF1 | c.29G>A p.R10Q | Missense Mutation (SNP) | VAF 229/351 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.313); catalogued as rs775664953, COSV100565913; called by muse, mutect2, varscan2
- EBF2 | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 224/360 reads (62%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.184); catalogued as COSV68775882; called by muse, mutect2, varscan2
- ECE1 | c.139-6C>T | Splice Region (SNP) | VAF 198/794 reads (25%) | catalogued as rs1001128787; called by muse, mutect2, varscan2
- EFCAB6 | c.3260G>A p.G1087E | Missense Mutation (SNP) | VAF 113/253 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs781531325; called by muse, varscan2
- EIF4G3 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 89/388 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.067); catalogued as COSV51681367; called by muse, mutect2, varscan2
- ELAVL4 | c.100C>G p.P34A | Missense Mutation (SNP) | VAF 119/568 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV63915506; called by muse, mutect2, varscan2
- EML5 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 219/604 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs375543692; called by muse, mutect2, varscan2
- ENPP1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 114/269 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as rs201300555; called by muse, mutect2, varscan2
- ENTPD4 | c.1154A>G p.Y385C | Missense Mutation (SNP) | VAF 127/371 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); catalogued as rs1200293083; called by muse, mutect2, varscan2
- EP400 | c.6877C>T p.R2293C | Missense Mutation (SNP) | VAF 128/356 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433414794, COSV57763285; called by muse, mutect2, varscan2
- EPB41L2 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 158/338 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs267600809; called by muse, varscan2
- EPHA6 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 192/408 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67576033; called by muse, mutect2, varscan2
- EPHB4 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 151/972 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs754054238; called by muse, mutect2, varscan2
- EPHB6 | c.1708G>A p.G570S | Missense Mutation (SNP) | VAF 515/1108 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1234796491, COSV63891356, COSV63891416; called by muse, mutect2, varscan2
- EPHB6 | c.2834C>T p.A945V | Missense Mutation (SNP) | VAF 282/945 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV63892370; called by muse, mutect2, varscan2
- ERC2 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 259/490 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV55626230; called by muse, varscan2
- ERVW-1 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 89/622 reads (14%) | SIFT tolerated (0.82); PolyPhen benign (0.066); catalogued as rs757185239; called by muse, mutect2, varscan2
- EVPL | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 434/434 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs1483766206; called by muse, varscan2
- EXOC3L2 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 341/527 reads (65%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.497); catalogued as rs1293953135; called by muse, mutect2, varscan2
- EZH1 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 226/351 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101331434; called by muse, mutect2, varscan2
- F11 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 193/374 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as COSV53008558; called by muse, mutect2, varscan2
- F5 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 295/412 reads (72%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); catalogued as rs778572956; called by muse, mutect2, varscan2
- FAIM2 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 89/323 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs746490841; called by muse, mutect2, varscan2
- FAM135B | c.2711C>T p.P904L | Missense Mutation (SNP) | VAF 149/427 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV99420005; called by muse, mutect2, varscan2
- FAM160A2 | c.1775C>T p.T592I (on ENST00000449352 / NM_001098794.2; = p.T606I on NM_032127.4) | Missense Mutation (SNP) | VAF 400/583 reads (69%) | SIFT tolerated (0.08); PolyPhen benign (0.22); catalogued as rs748524729; called by muse, mutect2, varscan2
- FAM163B | c.194T>C p.V65A | Missense Mutation (SNP) | VAF 565/568 reads (99%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs1485367084; called by muse, mutect2, varscan2
- FAM170B | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 164/498 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs866574926, COSV61253270; called by muse, varscan2
- FAM170B | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 130/392 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); catalogued as COSV61253742; called by muse, varscan2
- FAM171A2 | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 659/659 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs879328636; called by muse, mutect2, varscan2
- FAM171B | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 130/452 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59002747; called by muse, mutect2, varscan2
- FAM186B | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 174/280 reads (62%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as rs753838024; called by muse, mutect2, varscan2
- FAM216B | c.20G>A p.R7K | Missense Mutation (SNP) | VAF 194/277 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs531732949; called by muse, mutect2, varscan2
- FAM222A | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 143/492 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.244); catalogued as COSV62722977, COSV62723032; called by muse, mutect2, varscan2
- FAM234A | c.1624C>T p.R542W | Missense Mutation (SNP) | VAF 193/322 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372571002; called by muse, mutect2, varscan2
- FAM3B | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 152/814 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs970237251, COSV63613053; called by muse, mutect2
- FAM47B | c.1411G>A p.D471N | Missense Mutation (SNP) | VAF 302/488 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as COSV61454731; called by muse, mutect2, varscan2
- FAM47C | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 276/416 reads (66%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.643); catalogued as COSV63723958; called by muse, varscan2
- FAM83H | c.3403C>T p.R1135C | Missense Mutation (SNP) | VAF 197/669 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as rs1272345829; called by muse, mutect2, varscan2
- FAR1 | c.1420C>T p.L474F | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as rs1383643580; called by muse, mutect2, varscan2
- FASN | c.4649C>T p.S1550L | Missense Mutation (SNP) | VAF 267/669 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as rs759056728, COSV100147801; called by muse, mutect2, varscan2
- FAT2 | c.5171C>T p.S1724L | Missense Mutation (SNP) | VAF 117/492 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as rs144779956; called by muse, mutect2, varscan2
- FAT4 | c.6568C>T p.R2190C | Missense Mutation (SNP) | VAF 200/431 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765922495, COSV100628797; called by muse, mutect2, varscan2
- FAT4 | c.8060G>A p.R2687Q | Missense Mutation (SNP) | VAF 173/387 reads (45%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs777764521, COSV58675395; called by muse, mutect2, varscan2
- FAT4 | c.9896G>A p.R3299H | Missense Mutation (SNP) | VAF 172/339 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs370611770, COSV58687349; called by muse, mutect2, varscan2
- FBXL4 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 164/344 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs1018430772; called by muse, mutect2, varscan2
- FBXO43 | c.2122C>T p.L708F | Missense Mutation (SNP) | VAF 127/186 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751863250; called by muse, mutect2, varscan2
- FCRL3 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 55/297 reads (19%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.838); catalogued as COSV63840765, COSV63841174; called by muse, mutect2, varscan2
- FCRL5 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 112/553 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as rs890785912, COSV62510933; called by muse, mutect2, varscan2
- FER1L6 | c.3584C>T p.T1195I | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.307); catalogued as rs1468622183, COSV67550762; called by muse, mutect2, varscan2
- FGF11 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 434/435 reads (100%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1341209409; called by muse, mutect2, varscan2
- FGF13 | c.104C>T p.S35F | Missense Mutation (SNP) | VAF 281/281 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV101003642; called by muse, mutect2, varscan2
- FGF4 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 199/807 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs1359046966; called by muse, mutect2, varscan2
- FGFR1 | c.1229G>A p.S410N (on ENST00000447712 / NM_023110.3; = p.S408N on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 243/364 reads (67%) | SIFT tolerated (0.27); PolyPhen benign (0.073); catalogued as rs750688817; called by muse, mutect2, varscan2
- FHIT | c.196G>A p.G66R | Missense Mutation (SNP) | VAF 225/474 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs769130211, COSV59286231, COSV59319274; called by muse, mutect2, varscan2
- FLG | c.7349C>T p.S2450F | Missense Mutation (SNP) | VAF 132/599 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs753498822; called by muse, mutect2, varscan2
- FLG | c.4982C>T p.S1661F | Missense Mutation (SNP) | VAF 352/483 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1327217833; called by muse, mutect2, varscan2
- FLNA | c.6380G>A p.G2127D (on ENST00000369850 / NM_001110556.2; = p.G2119D on NM_001456.3) | Missense Mutation (SNP) | VAF 351/354 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as COSV100775341; called by muse, mutect2, varscan2
- FLNB | c.4745C>T p.P1582L | Missense Mutation (SNP) | VAF 242/515 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761987579; called by muse, mutect2, varscan2
- FLNC | c.7408C>A p.P2470T | Missense Mutation (SNP) | VAF 288/719 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57952953; called by muse, mutect2, varscan2
- FLT3 | c.1977G>T p.M659I | Missense Mutation (SNP) | VAF 104/384 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as COSV54056547; called by muse, mutect2, varscan2
- FMO1 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 177/266 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV61444890; called by muse, mutect2, varscan2
- FNBP4 | c.1238G>A p.R413K | Missense Mutation (SNP) | VAF 195/257 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1283641031; called by muse, mutect2, varscan2
- FNDC1 | c.2600C>T p.S867F | Missense Mutation (SNP) | VAF 237/542 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.311); catalogued as COSV99794652, COSV99796994; called by muse, mutect2, varscan2
- FNDC1 | c.3574A>G p.K1192E | Missense Mutation (SNP) | VAF 295/677 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.17); catalogued as rs1436597988; called by muse, mutect2
- FNDC3A | c.2738del p.Y913Lfs*19 (on ENST00000492622 / NM_001079673.2; = p.Y857Lfs*19 on NM_014923.5) | Frame Shift Del (DEL) | VAF 368/615 reads (60%) | catalogued as COSV68133874; called by mutect2, pindel, varscan2
- FOLH1 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 92/192 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as rs763728006, COSV57048090; called by muse, varscan2
- FOXO3 | c.173C>T p.P58L | Missense Mutation (SNP) | VAF 286/669 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs369034038; called by muse, varscan2
- FPR3 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 435/436 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV59331854; called by muse, mutect2, varscan2
- FRAT1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 149/218 reads (68%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as rs1164247119; called by muse, mutect2, varscan2
- FREM1 | c.4017G>A p.M1339I | Missense Mutation (SNP) | VAF 284/503 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1467385477, COSV101084924; called by muse, mutect2, varscan2
- FREM1 | c.2764G>A p.D922N | Missense Mutation (SNP) | VAF 291/732 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs747401637, COSV66526834; called by muse, mutect2, varscan2
- FREM3 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 327/618 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.428); catalogued as rs765394388; called by muse, mutect2, varscan2
- FTO | c.1385G>A p.R462Q | Missense Mutation (SNP) | VAF 93/286 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.035); catalogued as rs779678337; called by muse, mutect2, varscan2
- FUT9 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 195/474 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs765684352, COSV56142633, COSV56148853; called by muse, mutect2, varscan2
- FYB1 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 136/443 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.087); catalogued as COSV60940176, COSV60947622; called by muse, mutect2, varscan2
- FYB2 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 300/428 reads (70%) | catalogued as rs747637853, COSV58589627; called by muse, mutect2
- GAB1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 211/436 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as rs1338997103; called by muse, mutect2, varscan2
- GAL3ST1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 278/604 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs1354255119, COSV58891846, COSV58892092; called by muse, varscan2
- GALNT17 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 394/952 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as rs761319548, COSV61149532, COSV61173595; called by muse, mutect2, varscan2
- GALNT2 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 81/349 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs139591495; called by mutect2, varscan2
- GCSAML | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 259/348 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV63579327; called by muse, mutect2, varscan2
- GHDC | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 487/487 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as rs1199912731; called by muse, mutect2, varscan2
- GIGYF2 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 218/683 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101003753; called by muse, mutect2, varscan2
- GJA1 | c.359G>A p.G120D | Missense Mutation (SNP) | VAF 230/463 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.218); catalogued as COSV99246736; called by muse, mutect2, varscan2
- GJA9 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 323/463 reads (70%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs774074470; called by muse, mutect2, varscan2
- GK2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 186/378 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs149134428, COSV62626058, COSV62628077; called by muse, mutect2, varscan2
- GLB1L3 | c.1672C>T p.R558C | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as rs543697948, COSV104435109; called by muse, mutect2, varscan2
- GLDN | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 204/456 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.187); catalogued as rs1235082079; called by muse, mutect2, varscan2
- GLI2 | c.2827G>A p.E943K (on ENST00000361492 / NM_001374353.1; = p.E960K on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 361/695 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.249); catalogued as rs1276841941, COSV58037424; called by muse, mutect2, varscan2
- GLI2 | c.3538G>A p.G1180S (on ENST00000361492 / NM_001374353.1; = p.G1197S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 354/705 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as rs1221545910; called by muse, mutect2, varscan2
- GLIS3 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 231/608 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1264261637, COSV100173705; called by muse, mutect2, varscan2
- GLRB | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 98/201 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as COSV100029645, COSV52417998; called by muse, mutect2, varscan2
- GOLGA1 | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 182/283 reads (64%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV65228581; called by muse, mutect2, varscan2
- GOLGA3 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 287/443 reads (65%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs138174554; called by muse, mutect2, varscan2
- GPAT3 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 203/422 reads (48%) | catalogued as rs143173203; called by muse, mutect2, varscan2
- GPC2 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 147/552 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs538022806; called by muse, mutect2, varscan2
- GPC5 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 279/384 reads (73%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs775617391, COSV65582771; called by muse, mutect2, varscan2
- GPD1 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 247/345 reads (72%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs746425080; called by muse, mutect2, varscan2
- GPNMB | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 182/446 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as rs1432050888, COSV51700285; called by muse, mutect2, varscan2
- GPR27 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 171/370 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.481); catalogued as rs1468201853; called by muse, mutect2, varscan2
- GPR35 | c.361C>T p.P121S | Missense Mutation (SNP) | VAF 434/1350 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771907692; called by muse, mutect2
- GRB10 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 145/983 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs780776923, COSV60010172; called by muse, mutect2, varscan2
- GREB1L | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 190/360 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs868670954, COSV52550880; called by muse, mutect2, varscan2
- GRID2 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 216/474 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs754110902, COSV56172424; called by muse, mutect2, varscan2
- GRIN2A | c.2786C>T p.S929F | Missense Mutation (SNP) | VAF 112/321 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs767268773, COSV58041369; called by muse, mutect2, varscan2
- GRIN2B | c.4255C>T p.P1419S | Missense Mutation (SNP) | VAF 138/509 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101663199; called by muse, mutect2, varscan2
- GRM6 | c.2069C>T p.P690L | Missense Mutation (SNP) | VAF 280/411 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV51436029; called by muse, mutect2, varscan2
- GRM6 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 219/316 reads (69%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV99179460; called by muse, mutect2, varscan2
- GRM8 | c.2255C>T p.S752L | Missense Mutation (SNP) | VAF 209/756 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.072); catalogued as COSV58830556; called by muse, mutect2, varscan2
- GRM8 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 680/988 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58806253; called by muse, mutect2, varscan2
- GRXCR1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 160/349 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV67671586; called by muse, varscan2
- GTF2E1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 117/251 reads (47%) | SIFT tolerated (0.66); PolyPhen benign (0.03); catalogued as rs758063838; called by muse, mutect2, varscan2
- GYS2 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 117/383 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as COSV53926502; called by muse, mutect2, varscan2
- H2BW1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 267/409 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.269); catalogued as rs782518895, COSV54220841; called by muse, mutect2, varscan2
- HBB | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 292/405 reads (72%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs33932070, COSV100092912; ClinVar: other; called by muse, mutect2, varscan2
- HCN1 | c.1777C>T p.R593* | Nonsense Mutation (SNP) | VAF 179/179 reads (100%) | catalogued as COSV57491564; called by muse, mutect2, varscan2
- HCN3 | c.1627C>T p.R543W | Missense Mutation (SNP) | VAF 145/673 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144688517; called by muse, mutect2, varscan2
- HDX | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 273/273 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267606522, COSV52973149; called by muse, mutect2, varscan2
- HECTD4 | c.13049G>A p.G4350E | Missense Mutation (SNP) | VAF 304/491 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs375635285; called by muse, mutect2, varscan2
- HECW1 | c.4270T>C p.S1424P | Missense Mutation (SNP) | VAF 413/614 reads (67%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as COSV67834613; called by muse, mutect2, varscan2
- HERC1 | c.5734C>T p.R1912C | Missense Mutation (SNP) | VAF 447/447 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1250594628, COSV71247658; called by muse, mutect2, varscan2
- HEXA | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 232/434 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV51509046; called by muse, varscan2
- HHLA2 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 212/446 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.202); catalogued as rs764478334, COSV99071211; called by muse, varscan2
- HID1 | c.96G>A p.W32* | Nonsense Mutation (SNP) | VAF 643/646 reads (100%) | catalogued as rs1332483429, COSV100585933; called by muse, mutect2, varscan2
- HINFP | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 113/435 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760606813, COSV63432352; called by muse, mutect2, varscan2
- HIVEP3 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 437/589 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1388962007; called by muse, mutect2, varscan2
- HMGXB4 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 213/468 reads (46%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.005); catalogued as rs1415883925; called by muse, mutect2, varscan2
- HOOK1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 63/276 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969136; called by muse, mutect2, varscan2
- HOXC13 | c.659C>A p.S220Y | Missense Mutation (SNP) | VAF 279/448 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV99673445; called by muse, mutect2, varscan2
- HPS4 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 216/400 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs2331251, COSV61102968; called by muse, mutect2, varscan2
- HPSE | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 105/224 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs527684134, COSV100264338; called by muse, mutect2, varscan2
- HPSE2 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 257/388 reads (66%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.641); catalogued as COSV65187926; called by muse, mutect2, varscan2
- HSPA1L | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 238/524 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs770600264, COSV65149092; called by muse, varscan2
- HTR1A | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 629/630 reads (100%) | SIFT tolerated (0.43); PolyPhen benign (0.157); catalogued as COSV100108823; called by muse, mutect2, varscan2
- HTR2A | c.1212A>C p.K404N | Missense Mutation (SNP) | VAF 81/323 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV66327076; called by muse, mutect2, varscan2
- HYDIN | c.4930C>T p.R1644C | Missense Mutation (SNP) | VAF 179/281 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs993703682, COSV59255296; called by muse, mutect2, varscan2
- HYI | c.680G>A p.R227Q (on ENST00000372434 / NM_001330526.2; = p.R202Q on NM_031207.6) | Missense Mutation (SNP) | VAF 95/439 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.066); catalogued as rs773007194; called by muse, mutect2, varscan2
- ICA1 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 241/566 reads (43%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.986); catalogued as rs778660693, COSV55579052; called by muse, mutect2, varscan2
- IFI30 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 155/239 reads (65%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as COSV69576348; called by muse, mutect2, varscan2
- IFIT1B | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 272/272 reads (100%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs1455026168, COSV65663819; called by muse, mutect2, varscan2
- IFNA2 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 145/350 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66505368, COSV66505777; called by muse, mutect2, varscan2
- IFT172 | c.3637G>A p.E1213K | Missense Mutation (SNP) | VAF 273/576 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs760768488; called by muse, mutect2, varscan2
- IGF1 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 109/368 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1214292132, COSV61031432; called by muse, mutect2, varscan2
- IGF2 | c.524G>A p.W175* (on ENST00000434045 / NM_001127598.3; = p.W119* on NM_000612.6) | Nonsense Mutation (SNP) | VAF 510/710 reads (72%) | catalogued as rs868243135, COSV56101911; called by muse, mutect2, varscan2
- IGF2R | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 186/396 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV63628130; called by muse, mutect2, varscan2
- IGFBP4 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 529/529 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV99511192; called by muse, mutect2, varscan2
- IGHG3 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 322/754 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs374103999; called by muse, mutect2, varscan2
- IGHV3-13 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 246/284 reads (87%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.848); catalogued as rs1555437223; called by muse, mutect2, varscan2
- IGHV3-49 | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 190/462 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs541765310; called by muse, varscan2
- IGKV1-8 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 171/462 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.529); catalogued as rs974728367; called by muse, mutect2, varscan2
- IGKV1D-42 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 200/451 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs749575888; called by muse, mutect2, varscan2
- IGKV2-28 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as rs1466386564; called by muse, mutect2, varscan2
- IGKV3-15 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 80/411 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1268040011; called by muse, varscan2
- IGLJ4 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 203/439 reads (46%) | catalogued as rs767173494; called by muse, mutect2, varscan2
- IGSF10 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 175/349 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs746257775, COSV56792481; called by muse, mutect2, varscan2
- IKZF2 | c.1387G>A p.G463R | Missense Mutation (SNP) | VAF 204/719 reads (28%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.721); catalogued as rs769927583, COSV59576522; called by muse, mutect2, varscan2
- IL18RAP | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 193/435 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV51825261, COSV51828191; called by muse, mutect2, varscan2
- IL18RAP | c.994C>T p.R332C | Missense Mutation (SNP) | VAF 244/451 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV51825778; called by muse, mutect2, varscan2
- IL23R | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 121/446 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV61376316; called by muse, mutect2, varscan2
- IL25 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 187/511 reads (37%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs759770968; called by muse, mutect2, varscan2
- IL7R | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 254/255 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57406650; called by muse, mutect2, varscan2
- INF2 | c.2681C>T p.A894V | Missense Mutation (SNP) | VAF 283/837 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99384450; called by muse, mutect2
- INHBA | c.800G>A p.G267E | Missense Mutation (SNP) | VAF 747/1093 reads (68%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.191); catalogued as COSV99637016, COSV99637749; called by muse, mutect2, varscan2
- INTS6L | c.1102C>T p.P368S | Missense Mutation (SNP) | VAF 145/230 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66085729; called by muse, mutect2, varscan2
- IQCA1 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 289/846 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1176186919, COSV54515234; called by muse, mutect2, varscan2
- IQCF1 | c.193C>T p.L65F | Missense Mutation (SNP) | VAF 126/238 reads (53%) | SIFT tolerated (0.71); PolyPhen benign (0.043); catalogued as rs1236111095; called by muse, varscan2
- IQSEC3 | c.2302G>A p.E768K (on ENST00000538872 / NM_001170738.2; = p.E465K on NM_015232.1) | Missense Mutation (SNP) | VAF 152/527 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.249); catalogued as rs782575514, COSV58280759, COSV58281502; called by muse, varscan2
- IQUB | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 169/433 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as rs1267303204; called by muse, mutect2, varscan2
- IRF6 | c.269G>A p.S90N | Missense Mutation (SNP) | VAF 109/486 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM092334; called by muse, mutect2, varscan2
- ISX | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 169/320 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58085634; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 243/493 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs1399371668; called by muse, mutect2, varscan2
- ITCH | c.205C>T p.L69F | Missense Mutation (SNP) | VAF 78/338 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.263); catalogued as COSV99392974; called by muse, mutect2, varscan2
- ITGA4 | c.1360C>T p.R454W | Missense Mutation (SNP) | VAF 203/462 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs201906563, COSV51998072; called by muse, mutect2, varscan2
- ITGAD | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 138/230 reads (60%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV66759403; called by muse, mutect2, varscan2
- ITGAD | c.3150G>A p.W1050* | Nonsense Mutation (SNP) | VAF 61/212 reads (29%) | catalogued as COSV54932372; called by muse, mutect2, varscan2
- ITGAV | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 150/310 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV53710410; called by muse, mutect2, varscan2
- ITGB3 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 727/727 reads (100%) | SIFT tolerated (0.9); PolyPhen benign (0.014); catalogued as rs150951945; called by muse, mutect2, varscan2
- ITPKC | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 218/303 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs904288189, COSV54573896; called by muse, mutect2, varscan2
- ITPR2 | c.4728G>A p.M1576I | Missense Mutation (SNP) | VAF 104/362 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.119); catalogued as COSV101189975; called by muse, varscan2
- JAG2 | c.1602G>A p.E534= | Splice Region (SNP) | VAF 242/594 reads (41%) | catalogued as rs1210145719; called by muse, mutect2
- JPH2 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 198/789 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs751173523, COSV100881811; called by muse, mutect2, varscan2
- KALRN | c.2450G>A p.R817Q | Missense Mutation (SNP) | VAF 210/467 reads (45%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); catalogued as COSV53754710; called by muse, mutect2, varscan2
- KALRN | c.6482G>A p.R2161K (on ENST00000360013 / NM_001024660.4; = p.R464K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 199/379 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99362034; called by muse, mutect2, varscan2
- KBTBD3 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 246/475 reads (52%) | catalogued as rs1330796361, COSV73241195; called by muse, mutect2, varscan2
- KCNA6 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 148/421 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV54974759; called by muse, mutect2, varscan2
- KCND3 | c.1033G>A p.G345S | Missense Mutation (SNP) | VAF 98/339 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.224); catalogued as rs751093070, COSV56189680; called by muse, mutect2, varscan2
- KCNH2 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 267/935 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV100061231, COSV51133689, COSV51228014; called by muse, mutect2, varscan2
- KCNH7 | c.3302G>A p.R1101Q | Missense Mutation (SNP) | VAF 176/369 reads (48%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs770314357, COSV59782932; called by muse, mutect2, varscan2
- KCNK13 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 344/570 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs772965269, COSV56411318; called by muse, mutect2, varscan2
- KCNK18 | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 128/418 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57973469; called by muse, mutect2, varscan2
- KCNQ3 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 268/400 reads (67%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1448580874; called by muse, varscan2
- KCNU1 | c.2845G>A p.D949N | Missense Mutation (SNP) | VAF 111/392 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV67753032; called by muse, mutect2, varscan2
- KCP | c.3014C>T p.P1005L (on ENST00000620378; = p.P1065L on NM_001366122.1) | Missense Mutation (SNP) | VAF 349/1192 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.046); catalogued as rs772885225; called by muse, mutect2, varscan2
- KCTD11 | c.583C>T p.H195Y (on ENST00000333751 / NM_001363642.1; = p.H156Y on NM_001002914.2) | Missense Mutation (SNP) | VAF 557/560 reads (99%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs1423096454; called by muse, mutect2, varscan2
- KHSRP | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 120/460 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs748262672; called by muse, mutect2, varscan2
- KIAA1217 | c.1732C>T p.Q578* | Nonsense Mutation (SNP) | VAF 91/287 reads (32%) | catalogued as COSV56818381; called by muse, mutect2, varscan2
- KIAA1549 | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 91/710 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99652277; called by muse, mutect2, varscan2
- KIAA1549 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 351/767 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.27); catalogued as rs376519473; called by muse, mutect2, varscan2
- KIAA1586 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 161/385 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs575426890; called by muse, mutect2, varscan2
- KIAA1614 | c.2273C>T p.S758L | Missense Mutation (SNP) | VAF 186/709 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs575391757, COSV62551133; called by muse, mutect2, varscan2
- KIAA1755 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 311/427 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as COSV54074576; called by muse, mutect2, varscan2
- KIF13B | c.2776C>T p.H926Y | Missense Mutation (SNP) | VAF 71/238 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs771787654, COSV72954513; called by muse, mutect2, varscan2
- KIF21A | c.4099C>T p.R1367C (on ENST00000361418 / NM_001378440.1; = p.R1354C on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/218 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as rs756337041, COSV62767529; called by muse, mutect2, varscan2
- KIF26B | c.4205G>A p.R1402Q | Missense Mutation (SNP) | VAF 417/794 reads (53%) | SIFT tolerated (0.34); PolyPhen benign (0.09); catalogued as rs200347978, COSV63643833; called by muse, mutect2, varscan2
- KIF6 | c.1394G>A p.R465Q | Missense Mutation (SNP) | VAF 164/283 reads (58%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs745653601; called by muse, mutect2, varscan2
- KL | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 91/361 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); catalogued as rs267603803, COSV66307745; called by muse, mutect2, varscan2
- KLHL1 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 285/682 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV64771832; called by muse, mutect2, varscan2
- KLHL13 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 264/416 reads (63%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs182356687, COSV53244944; called by muse, mutect2, varscan2
- KLHL30 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 328/1004 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779828832; called by muse, varscan2
- KLHL32 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 221/442 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV65111804; called by muse, mutect2, varscan2
- KLLN | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 179/517 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs1201621687; called by muse, mutect2, varscan2
- KLRC2 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 105/199 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs375539764, COSV101122642; called by muse, mutect2, varscan2
- KMT2E | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 44/528 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777952395, COSV99996741; called by muse, mutect2
- KMT5A | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 59/410 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.071); catalogued as COSV57863736; called by muse, varscan2
- KMT5C | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 211/612 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.017); catalogued as rs757162823; called by muse, mutect2, varscan2
- KNDC1 | c.2240G>A p.G747E | Missense Mutation (SNP) | VAF 630/632 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV58841590; called by muse, mutect2, varscan2
- KRT3 | c.1862A>G p.Q621R | Missense Mutation (SNP) | VAF 296/467 reads (63%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.021); catalogued as COSV100527296; called by muse, mutect2, varscan2
- KRT4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 67/231 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.041); catalogued as COSV53409771; called by muse, mutect2, varscan2
- KRTAP10-3 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 379/798 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1555920226, COSV59966762; called by muse, mutect2, varscan2
- KRTAP10-5 | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 171/885 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV59954524, COSV59968821; called by muse, mutect2, varscan2
- KRTAP10-9 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 403/885 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs1359595548, COSV100555228; called by muse, mutect2, varscan2
- KRTAP5-4 | c.368C>T p.S123F | Missense Mutation (SNP) | VAF 252/407 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as rs1264604225, COSV101294421; called by muse, mutect2, varscan2
- KRTAP9-9 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 561/584 reads (96%) | SIFT deleterious (0); catalogued as rs774844543; called by muse, mutect2, varscan2
- KTN1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 95/490 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68023862; called by muse, mutect2, varscan2
- L1TD1 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 205/271 reads (76%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.972); catalogued as rs763813062, COSV63133538; called by muse, mutect2, varscan2
- LAMA1 | c.4364C>T p.P1455L | Missense Mutation (SNP) | VAF 94/237 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67544252; called by muse, mutect2, varscan2
- LAMA2 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 147/301 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV104436732; called by muse, mutect2, varscan2
- LAMA3 | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 101/239 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); catalogued as rs772903420; called by muse, mutect2, varscan2
- LAMB3 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 231/306 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1370865288; called by muse, mutect2, varscan2
- LAMB4 | c.1474G>A p.G492R | Missense Mutation (SNP) | VAF 192/729 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52715752; called by muse, mutect2, varscan2
- LAMP5 | c.305G>A p.S102N | Missense Mutation (SNP) | VAF 126/551 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1363744729; called by muse, mutect2, varscan2
- LARP1 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 98/304 reads (32%) | PolyPhen benign (0); catalogued as COSV60428127; called by muse, mutect2, varscan2
- LARP4B | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 292/293 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV60223282; called by muse, mutect2, varscan2
- LCE1A | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 332/711 reads (47%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); catalogued as COSV58727006; called by muse, mutect2, varscan2
- LCT | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 259/507 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.754); catalogued as COSV51555802; called by muse, mutect2, varscan2
- LCT | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 313/630 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs761296720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LDHB | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 208/326 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV63364901; called by muse, mutect2, varscan2
- LEFTY2 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 137/596 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as rs1228908579; called by muse, mutect2, varscan2
- LEFTY2 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 139/599 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs1249268121; called by muse, mutect2, varscan2
- LGI2 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 151/326 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.342); catalogued as rs1485662889; called by muse, mutect2, varscan2
- LINGO2 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 438/440 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs144926745; called by muse, mutect2, varscan2
- LIPI | c.970C>T p.Q324* | Nonsense Mutation (SNP) | VAF 71/297 reads (24%) | catalogued as COSV60714809; called by muse, varscan2
- LMO3 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 70/227 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs751584255, COSV53781759; called by muse, mutect2, varscan2
- LMX1A | c.815C>T p.S272F | Missense Mutation (SNP) | VAF 102/413 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); catalogued as COSV54219692; called by muse, varscan2
- LOXHD1 | c.3709G>A p.G1237R | Missense Mutation (SNP) | VAF 114/232 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs935418540, COSV56062898; called by muse, mutect2, varscan2
- LPA | c.3355C>T p.P1119S | Missense Mutation (SNP) | VAF 146/332 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV60307977; called by muse, mutect2, varscan2
- LRFN5 | c.1603G>A p.G535R | Missense Mutation (SNP) | VAF 217/538 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99982410; called by muse, mutect2, varscan2
- LRIG1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 239/488 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs147639877, COSV56250668; called by muse, mutect2, varscan2
- LRP12 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 112/279 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as rs779021302, COSV99407504; called by muse, mutect2, varscan2
- LRP1B | c.2441G>A p.G814E | Missense Mutation (SNP) | VAF 217/412 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs775281520, COSV67282551; called by muse, mutect2, varscan2
- LRP1B | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 136/307 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67222488; called by muse, mutect2, varscan2
- LRRC32 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 307/616 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1280897286, COSV99477021; called by muse, mutect2, varscan2
- LRRIQ1 | c.3514C>T p.R1172* | Nonsense Mutation (SNP) | VAF 66/242 reads (27%) | catalogued as rs148400374; called by muse, varscan2
- LRRN1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 236/466 reads (51%) | SIFT tolerated (0.69); PolyPhen benign (0.428); catalogued as COSV100076412; called by muse, varscan2
- LRRN4 | c.2000G>A p.W667* | Nonsense Mutation (SNP) | VAF 268/603 reads (44%) | catalogued as rs1364254790; called by muse, mutect2, varscan2
- LSG1 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 295/634 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs750624185; called by muse, mutect2, varscan2
- LTA | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 356/824 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769344065, COSV69305078; called by muse, mutect2, varscan2
- LTBP1 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 147/339 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs546103699, COSV63181992; called by muse, mutect2, varscan2
- LTO1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 458/590 reads (78%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); catalogued as rs372155093; called by muse, varscan2
- LY75 | c.3137G>A p.R1046K | Missense Mutation (SNP) | VAF 169/358 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV99717144; called by muse, mutect2, varscan2
- LY9 | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 223/430 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54433731, COSV54437167; called by muse, mutect2, varscan2
- M1AP | c.1321C>G p.P441A | Missense Mutation (SNP) | VAF 276/531 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51847721; called by muse, mutect2, varscan2
- MAB21L2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 274/558 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298787047; called by muse, mutect2, varscan2
- MACF1 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 416/544 reads (76%) | catalogued as COSV58369638; called by muse, mutect2, varscan2
- MAGEB5 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 137/457 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.186); catalogued as rs181076768, COSV66868711; called by muse, mutect2, varscan2
- MAGEC1 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 152/530 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53570262; called by muse, mutect2, varscan2
- MAGEC1 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 253/421 reads (60%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.017); catalogued as rs764765365; called by muse, mutect2, varscan2
- MAGEC1 | c.1457C>A p.S486Y | Missense Mutation (SNP) | VAF 485/486 reads (100%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.608); catalogued as COSV99594590; called by muse, mutect2, varscan2
- MAGEC1 | c.3124G>A p.E1042K | Missense Mutation (SNP) | VAF 443/443 reads (100%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.549); catalogued as rs866197130, COSV53571500; called by muse, mutect2, varscan2
- MAGEE1 | c.2812G>A p.E938K | Missense Mutation (SNP) | VAF 167/449 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.855); catalogued as COSV63912015; called by muse, mutect2, varscan2
- MAGI2 | c.3424G>A p.D1142N | Missense Mutation (SNP) | VAF 340/509 reads (67%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV62684228; called by muse, mutect2, varscan2
- MAGI2 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 385/559 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV62663763; called by muse, mutect2, varscan2
- MALRD1 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 141/141 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1475129345; called by muse, mutect2, varscan2
- MAP3K4 | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 231/480 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV62330150; called by muse, mutect2, varscan2
- MAP3K5 | c.3880C>T p.P1294S | Missense Mutation (SNP) | VAF 112/222 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs267600831, COSV62889083; called by muse, mutect2, varscan2
- MAP4K3 | c.551C>T p.A184V | Missense Mutation (SNP) | VAF 137/303 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55712364; called by muse, mutect2, varscan2
- MAPK13 | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 198/416 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV99274803; called by muse, mutect2, varscan2
- MAPKAPK3 | c.630C>T p.A210= | Splice Region (SNP) | VAF 160/352 reads (45%) | catalogued as rs1387018762, COSV63596783; called by muse, mutect2, varscan2
- MAPT | c.745G>A p.G249R (on ENST00000262410 / NM_001377265.1; = p.G174R on NM_016835.4) | Missense Mutation (SNP) | VAF 1014/1016 reads (100%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.073); catalogued as rs1432673926; called by muse, mutect2, varscan2
- MAST3 | c.2531G>A p.R844Q | Missense Mutation (SNP) | VAF 491/491 reads (100%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.964); catalogued as rs576829491; called by muse, mutect2, varscan2
- MBD5 | c.82C>T p.R28C | Missense Mutation (SNP) | VAF 217/420 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs772364272, COSV101289867; called by muse, mutect2, varscan2
- MBD5 | c.3656C>T p.P1219L | Missense Mutation (SNP) | VAF 213/428 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as rs1289868922; called by muse, mutect2, varscan2
- MCF2 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as COSV58495475; called by muse, mutect2, varscan2
- MCOLN1 | c.1660C>T p.R554C | Missense Mutation (SNP) | VAF 368/559 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs369993104, COSV51173890; called by muse, mutect2, varscan2
- MDGA2 | c.1855C>T p.R619W (on ENST00000399232 / NM_001113498.2; = p.R321W on NM_182830.4) | Missense Mutation (SNP) | VAF 179/451 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs766117441, COSV62094062; called by muse, mutect2, varscan2
- ME1 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 170/390 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs773146004; called by muse, varscan2
- MED12L | c.2286G>C p.E762D | Missense Mutation (SNP) | VAF 132/270 reads (49%) | SIFT tolerated (0.89); PolyPhen probably damaging (0.956); catalogued as COSV104383326; called by muse, mutect2, varscan2
- MED12L | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 244/490 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56397229; called by muse, mutect2, varscan2
- MED30 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 61/227 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.247); catalogued as rs1412743911; called by muse, mutect2, varscan2
- MEGF10 | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 83/287 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57249059; called by muse, mutect2, varscan2
- MEOX2 | c.530G>A p.G177E | Missense Mutation (SNP) | VAF 143/515 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs867233014, COSV56288658; called by muse, mutect2, varscan2
- MEP1A | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 240/488 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs1386229821, COSV57919986; called by muse, mutect2, varscan2
- MEPE | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 236/491 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.156); catalogued as rs551712026, COSV63071744, COSV63073982; called by muse, mutect2, varscan2
- MGAM | c.1590G>A p.M530I | Missense Mutation (SNP) | VAF 73/479 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV72075393; called by muse, mutect2, varscan2
- MGAM2 | c.5146G>A p.E1716K | Missense Mutation (SNP) | VAF 49/451 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as rs867320788; called by muse, mutect2, varscan2
- MICALL2 | c.1331C>T p.S444F | Missense Mutation (SNP) | VAF 397/1408 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs375884427; called by muse, mutect2, varscan2
- MKLN1 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 202/500 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV61760286; called by muse, mutect2, varscan2
- MKRN3 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 294/296 reads (99%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs140349866; called by muse, mutect2, varscan2
- MLIP | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 168/347 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs146750385; called by muse, mutect2, varscan2
- MLXIPL | c.2351G>A p.G784E | Missense Mutation (SNP) | VAF 328/787 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57667342; called by muse, mutect2, varscan2
- MMD2 | c.529C>T p.L177F | Missense Mutation (SNP) | VAF 122/1510 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs774820274, COSV68661156; called by muse, mutect2
- MMEL1 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 139/513 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs765021621, COSV56526143; called by muse, mutect2, varscan2
- MMP3 | c.1227G>A p.W409* | Nonsense Mutation (SNP) | VAF 54/227 reads (24%) | catalogued as rs1280008452; called by muse, mutect2, varscan2
- MMRN1 | c.3139C>T p.R1047W | Missense Mutation (SNP) | VAF 166/322 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs368250909, COSV53333695; called by muse, varscan2
- MORC4 | c.1727G>A p.R576Q | Missense Mutation (SNP) | VAF 302/440 reads (69%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV55239939; called by muse, mutect2, varscan2
- MOXD1 | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 152/330 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV100382037; called by muse, mutect2, varscan2
- MROH2A | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 340/519 reads (66%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.962); catalogued as rs868639543; called by muse, mutect2, varscan2
- MROH2A | c.1952G>A p.R651Q | Missense Mutation (SNP) | VAF 117/346 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as rs863223390, COSV67681372; ClinVar: benign; called by muse, mutect2, varscan2
- MROH2B | c.2053C>T p.R685* | Nonsense Mutation (SNP) | VAF 137/137 reads (100%) | catalogued as rs377423987; called by muse, mutect2, varscan2
- MROH7 | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 96/549 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV100273334, COSV59878162; called by muse, mutect2, varscan2
- MRPL48 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 183/270 reads (68%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.591); catalogued as rs780118362, COSV58638744, COSV58639947; called by muse, mutect2, varscan2
- MRPS16 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 80/265 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV60285035; called by muse, mutect2, varscan2
- MUC16 | c.36895G>A p.D12299N | Missense Mutation (SNP) | VAF 198/199 reads (99%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs761092392; called by muse, mutect2, varscan2
- MUC16 | c.25451C>T p.S8484F | Missense Mutation (SNP) | VAF 381/383 reads (99%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.133); catalogued as rs780878857, COSV101199220; called by muse, mutect2, varscan2
- MUC16 | c.15355C>T p.P5119S | Missense Mutation (SNP) | VAF 245/250 reads (98%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.471); catalogued as COSV67449282; called by muse, mutect2, varscan2
- MUC16 | c.14602G>A p.E4868K | Missense Mutation (SNP) | VAF 102/321 reads (32%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.205); catalogued as COSV67484099; called by muse, mutect2, varscan2
- MUC16 | c.14601G>A p.M4867I | Missense Mutation (SNP) | VAF 100/319 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); catalogued as rs550349238, COSV67442601; called by muse, mutect2, varscan2
- MUC3A | c.7997G>A p.G2666E | Missense Mutation (SNP) | VAF 198/1816 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.537); catalogued as rs762464654, COSV60211557; called by muse, mutect2
- MUC4 | c.9229G>A p.D3077N | Missense Mutation (SNP) | VAF 203/1110 reads (18%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.55); catalogued as rs1393705653; called by mutect2, varscan2
- MUC4 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 445/904 reads (49%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.316); catalogued as COSV62131694; called by muse, mutect2, varscan2
- MUC4 | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 357/788 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as COSV100640474; called by muse, mutect2, varscan2
- MUC5B | c.9220C>T p.L3074F | Missense Mutation (SNP) | VAF 255/784 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs778083835; called by muse, mutect2, varscan2
- MUC6 | c.6212C>T p.T2071I | Missense Mutation (SNP) | VAF 186/814 reads (23%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as rs749553046; called by muse, varscan2
- MUC6 | c.3977G>A p.R1326Q | Missense Mutation (SNP) | VAF 213/898 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs201742888; called by muse, mutect2, varscan2
- MUC6 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 256/994 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); catalogued as rs1206334964, COSV101424561; called by muse, mutect2, varscan2
- MYCN | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 283/566 reads (50%) | catalogued as COSV99808583; called by muse, mutect2, varscan2
- MYF6 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 248/384 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99952956; called by muse, mutect2, varscan2
- MYH3 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 318/318 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1160002369, COSV56864439; called by muse, mutect2, varscan2
- MYH4 | c.5224C>T p.Q1742* | Nonsense Mutation (SNP) | VAF 230/230 reads (100%) | catalogued as COSV55113351; called by muse, mutect2, varscan2
- MYH4 | c.3220G>A p.E1074K | Missense Mutation (SNP) | VAF 315/317 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV55121228; called by muse, mutect2, varscan2
- MYO15A | c.5762G>A p.R1921Q | Missense Mutation (SNP) | VAF 439/440 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as rs763685950, COSV52757036; called by muse, mutect2, varscan2
- MYO15B | c.6019C>T p.P2007S | Missense Mutation (SNP) | VAF 426/737 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1368368184; called by muse, mutect2, varscan2
- MYO1A | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 101/273 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267603596; called by muse, mutect2, varscan2
- MYO1E | c.2852C>T p.P951L | Missense Mutation (SNP) | VAF 352/352 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs750410945; called by muse, mutect2, varscan2
- MYO7A | c.2716C>T p.R906C | Missense Mutation (SNP) | VAF 266/519 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as rs868923965, COSV68683826; called by muse, mutect2, varscan2
- MYO7B | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 175/384 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.552); catalogued as rs1331403857, COSV67345024; called by muse, mutect2, varscan2
- MYO7B | c.3862G>A p.E1288K | Missense Mutation (SNP) | VAF 357/701 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs758529828, COSV67346180; called by muse, mutect2, varscan2
- MYO7B | c.5080G>A p.D1694N | Missense Mutation (SNP) | VAF 388/809 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as rs373648776; called by muse, mutect2, varscan2
- MYO9A | c.6292C>T p.R2098* | Nonsense Mutation (SNP) | VAF 383/384 reads (100%) | catalogued as rs866994109; called by muse, mutect2, varscan2
- MYOF | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 101/168 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63708298; called by muse, mutect2, varscan2
- MYT1L | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 280/559 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV67709081; called by muse, mutect2, varscan2
- N4BP2 | c.2765C>T p.S922F | Missense Mutation (SNP) | VAF 156/324 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV54703431; called by muse, mutect2, varscan2
- NAALADL2 | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 176/394 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as rs373491589, COSV71984352; called by muse, mutect2, varscan2
- NAP1L2 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 192/561 reads (34%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.632); catalogued as COSV100999171; called by muse, mutect2, varscan2
- NAP1L3 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 163/483 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.382); catalogued as COSV59078213; called by muse, mutect2, varscan2
- NAT8L | c.705C>G p.F235L | Missense Mutation (SNP) | VAF 376/704 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as COSV59051635; called by muse, mutect2, varscan2
- NAV1 | c.2720C>T p.P907L | Missense Mutation (SNP) | VAF 140/632 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs771196258; called by muse, varscan2
- NCF1 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 176/1506 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56877479; called by muse, mutect2
- NCOA1 | c.1652C>T p.S551F | Missense Mutation (SNP) | VAF 288/592 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.453); catalogued as rs904180131, COSV56044336; called by muse, mutect2, varscan2
- NCSTN | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 85/386 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs770064036; called by muse, mutect2
- NEBL | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 207/209 reads (99%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.966); catalogued as rs1060503679, COSV65803121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEK11 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 127/310 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs142683282; called by muse, mutect2, varscan2
- NEXMIF | c.1371G>T p.K457N | Missense Mutation (SNP) | VAF 188/563 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV99282196; called by muse, mutect2, varscan2
- NFASC | c.2162G>A p.R721Q (on ENST00000339876 / NM_001378329.1; = p.R717Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/395 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.066); catalogued as rs768730398, COSV58364055; called by muse, mutect2, varscan2
- NFIX | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 285/412 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV62175687; called by muse, mutect2, varscan2
- NFKBIA | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 211/614 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs376762724; called by muse, mutect2, varscan2
- NLRP12 | c.985C>T p.R329W | Missense Mutation (SNP) | VAF 346/346 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs147810259; called by muse, mutect2, varscan2
- NLRP14 | c.2657C>T p.S886L | Missense Mutation (SNP) | VAF 99/396 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs891431323; called by muse, mutect2, varscan2
- NLRP3 | c.124G>A p.G42S | Missense Mutation (SNP) | VAF 121/556 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.751); catalogued as COSV60223275; called by muse, mutect2, varscan2
- NLRP7 | c.369G>A p.W123* | Nonsense Mutation (SNP) | VAF 314/314 reads (100%) | catalogued as COSV60179036; called by muse, mutect2, varscan2
- NLRP9 | c.741G>A p.W247* | Nonsense Mutation (SNP) | VAF 403/406 reads (99%) | catalogued as COSV60463821; called by muse, mutect2, varscan2
- NME8 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 93/570 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1044473414, COSV52253335; called by muse, mutect2, varscan2
- NMNAT3 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 173/334 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs774032862, COSV56158540; called by muse, mutect2, varscan2
- NNMT | c.602G>A p.S201N | Missense Mutation (SNP) | VAF 395/515 reads (77%) | SIFT tolerated (0.39); PolyPhen benign (0.439); catalogued as COSV55474359; called by muse, mutect2, varscan2
- NOL6 | c.1364G>A p.G455E | Missense Mutation (SNP) | VAF 205/571 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs531563377; called by muse, mutect2, varscan2
- NOS3 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 105/885 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs764127718; called by muse, mutect2, varscan2
- NOX5 | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 774/775 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV99534944; called by muse, mutect2, varscan2
- NPHP1 | c.1787G>A p.R596K (on ENST00000393272 / NM_207181.4; = p.R597K on NM_000272.5) | Missense Mutation (SNP) | VAF 159/358 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs766499997; called by muse, mutect2, varscan2
- NPHS1 | c.3266G>A p.R1089K | Missense Mutation (SNP) | VAF 294/296 reads (99%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs113252496; called by muse, mutect2, varscan2
- NPIPA5 | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 146/475 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1303667994; called by muse, mutect2, varscan2
- NPS | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 70/278 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV104432609, COSV67690678; called by muse, mutect2, varscan2
- NPY4R | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782582613, COSV65398634; called by muse, mutect2, varscan2
- NRCAM | c.331G>A p.E111K (on ENST00000379028 / NM_001371124.1; = p.E105K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 125/986 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.074); catalogued as rs140770274, COSV61036331; called by muse, mutect2, varscan2
- NRK | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 274/274 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1166798144, COSV54589199; called by muse, mutect2, varscan2
- NRK | c.3032G>A p.G1011E | Missense Mutation (SNP) | VAF 430/430 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1347043783; called by muse, mutect2, varscan2
- NRP2 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 148/448 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs935324633, COSV99783311; called by muse, mutect2, varscan2
- NRXN1 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 287/585 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58463010; called by muse, mutect2, varscan2
- NRXN1 | c.1012G>A p.G338R | Missense Mutation (SNP) | VAF 199/406 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58436858; called by muse, mutect2, varscan2
- NRXN3 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 90/482 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1335610727; called by muse, varscan2
- NT5C1B | c.796G>A p.E266K (on ENST00000359846 / NM_001199086.2; = p.E206K on NM_033253.4) | Missense Mutation (SNP) | VAF 274/634 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.222); catalogued as rs781054410, COSV58394503; called by muse, mutect2, varscan2
- NT5DC4 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 222/442 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.132); catalogued as rs1401573930; called by muse, mutect2, varscan2
- NT5E | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 208/417 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs946909778; called by muse, mutect2, varscan2
- NTRK3 | c.379C>A p.P127T | Missense Mutation (SNP) | VAF 350/351 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0.088); catalogued as COSV58144872; called by muse, mutect2, varscan2
- NUDT12 | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 101/345 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.649); catalogued as rs544325116, COSV50090562; called by muse, mutect2, varscan2
- NUDT8 | c.29G>A p.G10D | Missense Mutation (SNP) | VAF 114/348 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1342759139; called by muse, mutect2, varscan2
- NVL | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 94/517 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs866683945, COSV55869764, COSV55874438; called by muse, mutect2, varscan2
- OCIAD2 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 152/322 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56717356, COSV99906582; called by muse, mutect2, varscan2
- OLFM3 | c.875G>A p.G292E (on ENST00000338858 / NM_001288821.1; = p.G272E on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/489 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58796045; called by muse, mutect2, varscan2
- OR10A3 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 134/655 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62459253, COSV62460367; called by muse, mutect2, varscan2
- OR13C2 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 147/477 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101604882; called by muse, mutect2, varscan2
- OR14C36 | c.24G>A p.M8I | Missense Mutation (SNP) | VAF 68/357 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV58600698, COSV58601240; called by muse, mutect2, varscan2
- OR14C36 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 68/362 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs1351356830, COSV58601692; called by muse, mutect2, varscan2
- OR2A12 | c.730C>T p.L244F | Missense Mutation (SNP) | VAF 111/743 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV68822080; called by muse, mutect2, varscan2
- OR2AE1 | c.281T>C p.F94S | Missense Mutation (SNP) | VAF 258/993 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); catalogued as COSV60391258; called by muse, mutect2, varscan2
- OR2AK2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 198/415 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs764277744, COSV63550170; called by muse, mutect2, varscan2
- OR2AP1 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 279/419 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.759); catalogued as COSV58725555; called by muse, mutect2, varscan2
- OR2C3 | c.203C>T p.P68L | Missense Mutation (SNP) | VAF 129/583 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs762142020, COSV63576357; called by muse, mutect2, varscan2
- OR2D3 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 142/543 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99549715; called by muse, mutect2, varscan2
- OR2F1 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 335/788 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV67331227, COSV67331259; called by muse, mutect2, varscan2
- OR2J2 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 231/506 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs761974714; called by muse, mutect2, varscan2
- OR2L8 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 199/304 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267598488, COSV61728399; called by muse, mutect2
- OR2T12 | c.866G>A p.S289N | Missense Mutation (SNP) | VAF 95/364 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV58777466; called by muse, mutect2, varscan2
- OR2T27 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 238/817 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs532061959; called by muse, mutect2
- OR2T4 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 351/728 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs1370040503; called by muse, mutect2, varscan2
- OR2T4 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 175/800 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.104); catalogued as rs1015587715; called by muse, mutect2, varscan2
- OR4A15 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 312/456 reads (68%) | catalogued as COSV59034901; called by muse, varscan2
- OR4A15 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 265/403 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.86); catalogued as COSV59036263; called by muse, varscan2
- OR4A16 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 395/544 reads (73%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.082); catalogued as rs575051490, COSV59042137; called by muse, mutect2, varscan2
- OR4A5 | c.907T>A p.L303I | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.022); catalogued as COSV60522647, COSV60524530; called by muse, mutect2, varscan2
- OR4B1 | c.393G>A p.M131I | Missense Mutation (SNP) | VAF 114/491 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs1231985670, COSV100535504; called by muse, mutect2, varscan2
- OR4C12 | c.745T>A p.F249I | Missense Mutation (SNP) | VAF 69/466 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs1555020074; called by muse, mutect2, varscan2
- OR4C13 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 58/276 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV73648600; called by muse, mutect2, varscan2
- OR4C16 | c.178T>C p.F60L | Missense Mutation (SNP) | VAF 128/498 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as rs763510537; called by muse, mutect2
- OR4C6 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 400/516 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs868600897, COSV58602718; called by muse, mutect2, varscan2
- OR4D9 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 356/500 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV61435432; called by muse, mutect2, varscan2
- OR4K1 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 163/752 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs543752160, COSV53458720, COSV99579378; called by muse, mutect2, varscan2
- OR4N2 | c.455G>A p.G152D | Missense Mutation (SNP) | VAF 321/1578 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs769608239; called by muse, mutect2, varscan2
- OR4Q3 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 200/838 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59177294; called by muse, mutect2, varscan2
- OR4Q3 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 201/839 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59178476, COSV59180133; called by muse, mutect2, varscan2
- OR51A2 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 299/418 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100984987; called by muse, mutect2, varscan2
- OR51B4 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 226/290 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751333456, COSV66517335, COSV66517455; called by muse, mutect2, varscan2
- OR51G1 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 127/557 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58969219; called by muse, mutect2, varscan2
- OR51G2 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 82/406 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58991807; called by muse, mutect2, varscan2
- OR51Q1 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 141/308 reads (46%) | catalogued as COSV100333021; called by muse, mutect2, varscan2
- OR51T1 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 319/440 reads (73%) | SIFT tolerated (0.77); PolyPhen benign (0.022); catalogued as rs763704073; called by muse, mutect2, varscan2
- OR52B2 | c.697C>T p.Q233* | Nonsense Mutation (SNP) | VAF 293/400 reads (73%) | catalogued as rs1374598318; called by muse, mutect2, varscan2
- OR56A1 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 131/328 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV57363970; called by muse, mutect2, varscan2
3,052 further variants in this file (1,715 protein-altering or splice-affecting, 1,182 silent, 155 other) are not listed here.
